Somatic mutation profile of tumor specimen C3L-06715-01 (aliquot CPT0373420006) from CPTAC case C3L-06715, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 70.8 years (25,872 days).
Specimen C3L-06715-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd97bbda-452f-470c-b36f-a29b8b2c922c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06715-31 (Blood Derived Normal), aliquot CPT0374670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f530acb-e005-4f53-abff-3e4e04fd7241

The open-access MAF lists 231 somatic variants for this specimen: 150 protein-altering or splice-affecting, 78 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 78, Nonsense Mutation 14, Splice Region 2, Splice Site 1, Intron 1, 5'UTR 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AASDH | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 42/452 reads (9%) | catalogued as rs766223450; called by muse, mutect2
- ACADL | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 19/220 reads (9%) | catalogued as COSV99284917; called by muse, mutect2
- ADAMTS2 | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 56/700 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1328973142; called by muse, mutect2
- ANKS4B | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs751887530, COSV61138694; called by muse, mutect2, varscan2
- ATP2B1 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1226258789; called by muse, mutect2, varscan2
- ATP7A | c.4114A>G p.I1372V | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs1557238695; called by muse, mutect2
- BCL6B | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1286917895; called by muse, mutect2, varscan2
- C7 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472311; called by muse, mutect2, varscan2
- CCKAR | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 39/500 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs201762260; called by muse, mutect2
- CCNYL1 | c.532C>T p.P178S (on ENST00000295414 / NM_001330218.2; = p.P108S on NM_152523.2) | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs1438746028; called by muse, mutect2, varscan2
- CDH6 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs375392354; called by muse, mutect2, varscan2
- CDK5R1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 19/549 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV55580382; called by muse, mutect2
- CHST10 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51805301; called by muse, mutect2
- CLCA4 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.219); catalogued as COSV99760244; called by muse, mutect2, varscan2
- COL5A3 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272756674; called by muse, mutect2
- CTNND2 | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100478707; called by muse, mutect2
- DGKK | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 48/425 reads (11%) | catalogued as COSV65706472; called by muse, mutect2, varscan2
- DNAH14 | c.5897G>A p.W1966* (on ENST00000445597; = p.W2506* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | catalogued as COSV59897989; called by muse, mutect2, varscan2
- DNAH2 | c.5046G>A p.M1682I | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1011588300, COSV101209369; called by muse, mutect2
- EDIL3 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV56916147; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.81); catalogued as rs763951338; called by muse, mutect2
- FAM160B1 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1177495006; called by muse, mutect2
- FAM47A | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 55/536 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1183001792, COSV60494226; called by muse, mutect2, varscan2
- FYB2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1464948767, COSV100599172; called by muse, mutect2, varscan2
- GADL1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as rs1005268130; called by muse, mutect2
- HTR5A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 28/521 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs1205586113, COSV55282191, COSV55283276; called by muse, mutect2
- HYDIN | c.7486G>A p.D2496N | Missense Mutation (SNP) | VAF 63/513 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150902638; called by muse, mutect2, varscan2
- ITGB4 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 56/458 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs150962076; called by muse, mutect2, varscan2
- LRAT | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 27/270 reads (10%) | catalogued as COSV60476660; called by muse, mutect2
- LRP4 | c.2995C>T p.R999W | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1404612994; called by muse, mutect2
- MAGEC1 | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 35/423 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs763285093, COSV53567836, COSV53577256; called by muse, mutect2
- MAP7D3 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 55/506 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs750404312; called by muse, mutect2, varscan2
- MGAM | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV71886053; called by muse, mutect2
- MMP13 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV52824362; called by muse, mutect2
- MUC16 | c.10768G>A p.D3590N | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.139); catalogued as COSV67496833; called by muse, mutect2
- MUC16 | c.5198C>T p.S1733F | Missense Mutation (SNP) | VAF 42/454 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67476011, COSV67477614; called by muse, mutect2, varscan2
- MUC4 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 54/670 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs920723630; called by muse, mutect2
- MYL1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV58974567; called by muse, mutect2
- MYO18B | c.7448C>T p.S2483F | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100122485; called by muse, mutect2
- NETO1 | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 24/381 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.823); catalogued as COSV55015361; called by muse, mutect2
- NLRP2 | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 53/463 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs374020777; called by muse, mutect2, varscan2
- NPR1 | c.1759-1G>A p.X587_splice | Splice Site (SNP) | VAF 22/240 reads (9%) | catalogued as COSV100902088, COSV64118151; called by muse, mutect2
- NUMB | c.1037C>T p.S346L (on ENST00000355058; = p.S335L on NM_003744.5) | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.589); catalogued as rs763061486; called by muse, mutect2
- OR4C13 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV73648600; called by muse, mutect2
- OR7G1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 35/444 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs555730906, COSV99528464; called by muse, mutect2
- OTOGL | c.4117G>A p.E1373K (on ENST00000547103; = p.E1364K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755276225, COSV72007277; called by muse, mutect2
- PCDHA10 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 22/792 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.477); catalogued as rs782751627, COSV100251009; called by muse, mutect2
- PCDHA2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 38/569 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as rs539789047, COSV65365074; called by muse, mutect2
- PHF6 | c.716A>T p.H239L (on ENST00000332070 / NM_032458.3; = p.H240L on NM_032335.3) | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59701084; called by muse, varscan2
- PHRF1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs183571614; called by muse, mutect2
- PKD1 | c.6098C>T p.A2033V | Missense Mutation (SNP) | VAF 58/582 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs557932393; called by muse, mutect2
- PKIB | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV57798229; called by muse, mutect2
- PLA2G4A | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66552438; called by muse, mutect2
- PRB3 | c.791G>A p.G264E (on ENST00000381842; = p.G306E on NM_006249.5) | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.249); catalogued as rs753560704; called by muse, mutect2, varscan2
- PTGS2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66570927; called by muse, mutect2
- PTPRS | c.5534C>T p.P1845L | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257575436, COSV53617407; called by muse, mutect2
- RBMXL3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 62/585 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.017); catalogued as rs1453598911, COSV57754622; called by muse, mutect2, varscan2
- RFX7 | c.2777C>T p.P926L (on ENST00000559447 / NM_001368074.1; = p.P1023L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428385, COSV57963129; called by muse, mutect2
- RTL8B | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 64/628 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101195654; called by muse, mutect2, varscan2
- SHROOM4 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 58/584 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56786124; called by muse, mutect2
- SLITRK3 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1339910554, COSV53846803, COSV53848601; called by muse, mutect2
- SMPX | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs765928656, COSV65277400; called by muse, mutect2, varscan2
- SRC | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100658292; called by muse, mutect2
- SULT1C3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100227329, COSV104411586; called by muse, mutect2
- TLL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1452918005, COSV50269380; called by muse, mutect2
- TMC5 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 20/373 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs369805960; called by muse, mutect2
- TNXB | c.10808C>T p.P3603L (on ENST00000647633; = p.P3356L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1162946901, COSV64484940; called by muse, mutect2
- TRAV2 | c.86T>A p.V29E | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1404383270; called by muse, mutect2
- TRIM10 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 29/606 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1029732890; called by muse, mutect2
- UGT2B11 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV71423324; called by muse, mutect2
- USP15 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 10/301 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV99740919; called by muse, mutect2
- USP30 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.119); catalogued as COSV57451813; called by muse, mutect2
- ZCCHC12 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV59571518; called by muse, mutect2
- ZNF716 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.331); catalogued as COSV70779322; called by muse, mutect2
- ABCA6 | c.3416C>T p.T1139I | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABLIM3 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMDEC1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ADGRG4 | c.3518C>A p.P1173Q | Missense Mutation (SNP) | VAF 41/500 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ADHFE1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ARFGEF2 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 43/364 reads (12%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.3577G>T p.V1193L | Missense Mutation (SNP) | VAF 46/515 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- ATP1A2 | c.2599T>G p.F867V | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- BAHD1 | c.1772G>T p.W591L | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BCL11A | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC175 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- CCDC196 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- CD74 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- CDH7 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- CFAP54 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.745); called by muse, mutect2
- CHD6 | c.4607C>T p.A1536V | Missense Mutation (SNP) | VAF 44/461 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2
- CIB4 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 12/329 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- COL4A3 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); called by muse, mutect2
- COL6A5 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- CTSG | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 35/529 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.295); called by muse, mutect2
- CYP26A1 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- DCANP1 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2
- DEPDC7 | c.865C>T p.P289S (on ENST00000241051 / NM_001077242.2; = p.P280S on NM_139160.2) | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- DLG1 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2
- DNMT1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- EEF2K | c.1979_1986delinsT p.Q660Lfs*5 | Frame Shift Del (DEL) | VAF 49/500 reads (10%) | called by pindel, varscan2*
- EIF4A1 | c.631T>G p.L211V | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.954); called by muse, mutect2
- ELFN1 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 65/642 reads (10%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- EPHB3 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- EPRS1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FAM186A | c.3039G>A p.W1013* | Nonsense Mutation (SNP) | VAF 25/415 reads (6%) | called by muse, mutect2
- FNDC1 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNT11 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.054); called by muse, mutect2
- GEMIN5 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); called by muse, mutect2
- HELZ | c.2556C>A p.Y852* | Nonsense Mutation (SNP) | VAF 13/403 reads (3%) | called by muse, mutect2
- ICAM1 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2
- IFNA4 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 28/311 reads (9%) | called by muse, mutect2, varscan2
- IGHM | c.885G>C p.W295C | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IGLV3-1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IQCA1L | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.368); called by muse, mutect2
- ITGAD | c.2681G>C p.R894T | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.01); called by muse, mutect2
- LRRC42 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2
- MAP3K21 | c.2624G>A p.G875E | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MCF2 | c.2089C>G p.Q697E | Missense Mutation (SNP) | VAF 31/416 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- MYL1 | c.307C>T p.L103= | Splice Region (SNP) | VAF 15/235 reads (6%) | called by muse, mutect2
- NEB | c.11433G>A p.W3811* | Nonsense Mutation (SNP) | VAF 20/452 reads (4%) | called by muse, mutect2
- NRXN3 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 33/462 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.057); called by muse, mutect2
- NUP160 | c.2660A>G p.Q887R | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR10AC1 | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 25/540 reads (5%) | called by muse, mutect2
- PCLO | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2
- PLA2G2F | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- PLCB1 | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R2B | c.1207G>A p.E403K (on ENST00000394409; = p.E469K on NM_181674.2) | Missense Mutation (SNP) | VAF 56/406 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PRMT5 | c.1761G>A p.K587= | Splice Region (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- PTPRK | c.3061G>A p.E1021K (on ENST00000368215 / NM_001291984.2; = p.E1022K on NM_002844.4) | Missense Mutation (SNP) | VAF 35/394 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); called by muse, mutect2
- RASL12 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 46/540 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); called by muse, mutect2
- RBM19 | c.2383C>T p.Q795* | Nonsense Mutation (SNP) | VAF 28/348 reads (8%) | called by muse, mutect2
- RFPL4B | c.472T>C p.W158R | Missense Mutation (SNP) | VAF 41/386 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINI2 | c.224T>G p.L75* | Nonsense Mutation (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- SH3TC2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- SLC4A9 | c.2857C>A p.L953M (on ENST00000507527 / NM_001258428.2; = p.L929M on NM_031467.3) | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.467); called by muse, mutect2
- SLC6A14 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- SULT1C2 | c.413T>G p.V138G | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SYTL4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TAF1L | c.3133A>G p.I1045V | Missense Mutation (SNP) | VAF 25/653 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAOK1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAV2 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.33235G>A p.E11079K (on ENST00000591111; = p.E10152K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/580 reads (8%) | PolyPhen possibly damaging (0.851); called by muse, mutect2
- TTN | c.32995A>G p.K10999E (on ENST00000591111; = p.K10072E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/353 reads (8%) | PolyPhen benign (0.006); called by muse, mutect2
- VIL1 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZNF34 | c.1436A>T p.E479V | Missense Mutation (SNP) | VAF 18/475 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- ZNF667 | c.1154T>A p.L385Q | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- ZNF699 | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2
- ZSCAN5B | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); called by muse, mutect2
- ZSCAN5B | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2
- ABCA9 | c.2499G>A p.R833= | Silent (SNP) | VAF 44/375 reads (12%) | catalogued as rs1290470280; called by muse, mutect2, varscan2
- ABLIM3 | c.345C>T p.F115= | Silent (SNP) | VAF 38/282 reads (13%) | catalogued as COSV58647468; called by muse, mutect2, varscan2
- AC006059.2 | c.2136C>T p.F712= | Silent (SNP) | VAF 29/379 reads (8%) | catalogued as rs1178600513; called by muse, mutect2
- AC099489.1 | c.1275T>C p.P425= | Silent (SNP) | VAF 16/441 reads (4%) | catalogued as rs1246111511; called by muse, mutect2
- ADAM21 | c.1230G>A p.G410= | Silent (SNP) | VAF 12/340 reads (4%) | called by muse, mutect2
- ADAMTS18 | c.894C>T p.L298= | Silent (SNP) | VAF 49/501 reads (10%) | catalogued as rs748153604, COSV51417591; called by muse, mutect2
- ANAPC4 | c.933G>T p.G311= | Silent (SNP) | VAF 26/284 reads (9%) | catalogued as COSV59544888; called by muse, mutect2
- ANKUB1 | c.1014C>T p.V338= | Silent (SNP) | VAF 38/415 reads (9%) | called by muse, mutect2
- ANO3 | c.165C>T p.S55= | Silent (SNP) | VAF 42/421 reads (10%) | catalogued as rs747159500; called by muse, mutect2
- BACH2 | c.1158C>T p.T386= | Silent (SNP) | VAF 23/473 reads (5%) | called by muse, mutect2
- CA5A | c.870G>A p.R290= | Silent (SNP) | VAF 36/464 reads (8%) | called by muse, mutect2
- CFAP47 | c.2592C>T p.F864= | Silent (SNP) | VAF 44/372 reads (12%) | catalogued as COSV99934079; called by muse, mutect2, varscan2
- COL6A3 | c.3294G>A p.L1098= | Silent (SNP) | VAF 38/404 reads (9%) | catalogued as COSV55100940; called by muse, mutect2
- CSMD2 | c.4167G>A p.G1389= | Silent (SNP) | VAF 34/357 reads (10%) | catalogued as COSV53961748; called by muse, mutect2
- CSMD3 | c.3738G>A p.T1246= (on ENST00000297405 / NM_001363185.1; = p.T1142= on NM_052900.3) | Silent (SNP) | VAF 17/230 reads (7%) | catalogued as rs1395803496, COSV52117937, COSV52310072; ClinVar: likely benign; called by muse, mutect2
- DDX10 | c.1416C>T p.F472= | Silent (SNP) | VAF 18/207 reads (9%) | catalogued as rs368498022; called by muse, mutect2
- DEFB114 | c.153C>T p.S51= | Silent (SNP) | VAF 26/273 reads (10%) | catalogued as rs748018561, COSV59037168; called by muse, mutect2, varscan2
- DLL1 | c.1863C>T p.F621= | Silent (SNP) | VAF 21/638 reads (3%) | catalogued as rs767408730; called by muse, mutect2
- DOCK4 | c.5085G>A p.S1695= | Silent (SNP) | VAF 32/338 reads (9%) | catalogued as rs760333167; called by muse, mutect2
- DYSF | c.1923C>T p.V641= | Silent (SNP) | VAF 21/268 reads (8%) | called by muse, mutect2
- EYA4 | c.306C>T p.P102= | Silent (SNP) | VAF 51/357 reads (14%) | catalogued as COSV62046347; called by muse, mutect2, varscan2
- FKBP9 | c.84G>A p.A28= | Silent (SNP) | VAF 46/518 reads (9%) | catalogued as COSV54227794; called by muse, mutect2
- FRMD1 | c.834C>T p.I278= | Silent (SNP) | VAF 28/380 reads (7%) | called by muse, mutect2
- FSTL5 | c.697C>T p.L233= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- FUT9 | c.261C>T p.N87= | Silent (SNP) | VAF 27/430 reads (6%) | called by muse, mutect2
- GFY | c.111C>T p.A37= | Silent (SNP) | VAF 40/466 reads (9%) | called by muse, mutect2
- GUCA1B | c.558C>T p.P186= | Silent (SNP) | VAF 26/328 reads (8%) | catalogued as rs769205997; called by muse, mutect2
- IGHG3 | c.699C>A p.V233= | Silent (SNP) | VAF 25/420 reads (6%) | called by muse, mutect2
- IGLV3-1 | c.90C>T p.S30= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as rs375607652; called by muse, mutect2, varscan2
- IL18R1 | c.552C>T p.S184= | Silent (SNP) | VAF 22/394 reads (6%) | called by muse, mutect2
- KLHL13 | c.9G>A p.L3= | Silent (SNP) | VAF 29/320 reads (9%) | catalogued as rs1569430354, COSV53250234; called by muse, mutect2
- KRT33A | c.741C>T p.F247= | Silent (SNP) | VAF 25/352 reads (7%) | catalogued as rs779612307; called by muse, mutect2
- KRT74 | c.795G>A p.V265= | Silent (SNP) | VAF 28/382 reads (7%) | called by muse, mutect2
- LRRC66 | c.540C>T p.F180= | Silent (SNP) | VAF 13/336 reads (4%) | called by muse, mutect2
- MDC1 | c.264C>T p.I88= | Silent (SNP) | VAF 65/620 reads (10%) | called by muse, mutect2, varscan2
- MGAT4A | c.366T>C p.L122= | Silent (SNP) | VAF 20/347 reads (6%) | called by muse, mutect2
- MUC16 | c.17619G>A p.Q5873= | Silent (SNP) | VAF 32/320 reads (10%) | catalogued as rs767524541; called by muse, mutect2, varscan2
- NRXN1 | c.4245C>T p.I1415= | Silent (SNP) | VAF 42/422 reads (10%) | catalogued as rs1229381914; called by muse, mutect2, varscan2
- NUP205 | c.5718C>T p.R1906= | Silent (SNP) | VAF 29/276 reads (11%) | catalogued as COSV53654998; called by muse, mutect2, varscan2
- OIT3 | c.994C>T p.L332= | Silent (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- OR2L13 | c.78C>T p.L26= | Silent (SNP) | VAF 24/442 reads (5%) | catalogued as rs1161914661; called by muse, mutect2
- OR4Q2 | c.657C>G p.T219= | Silent (SNP) | VAF 29/302 reads (10%) | called by muse, mutect2, varscan2
- OR51D1 | c.702C>T p.I234= | Silent (SNP) | VAF 42/478 reads (9%) | catalogued as COSV62914224; called by muse, mutect2
- OR5AR1 | c.219C>T p.Y73= | Silent (SNP) | VAF 18/509 reads (4%) | catalogued as rs1387834332; called by muse, mutect2
- PCDH11X | c.813C>T p.L271= | Silent (SNP) | VAF 32/288 reads (11%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1371C>T p.F457= | Silent (SNP) | VAF 56/693 reads (8%) | catalogued as rs782069574, COSV50697736; called by muse, mutect2
- PCDHGA3 | c.198C>T p.I66= | Silent (SNP) | VAF 42/530 reads (8%) | catalogued as rs1350756695, COSV53924736; called by muse, mutect2
- PDPR | c.1395G>A p.R465= | Silent (SNP) | VAF 32/485 reads (7%) | called by muse, mutect2
- PDZRN4 | c.3051G>A p.G1017= (on ENST00000402685 / NM_001164595.2; = p.G759= on NM_013377.4) | Silent (SNP) | VAF 33/340 reads (10%) | catalogued as COSV100114191; called by muse, mutect2, varscan2
- PHKA2 | c.3450C>T p.L1150= | Silent (SNP) | VAF 55/532 reads (10%) | called by muse, mutect2, varscan2
- PHLDB2 | c.3732G>A p.G1244= (on ENST00000393925 / NM_001134439.2; = p.G1201= on NM_145753.2) | Silent (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- PIEZO2 | c.4969C>T p.L1657= | Silent (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- PIEZO2 | c.1218G>A p.Q406= | Silent (SNP) | VAF 25/334 reads (7%) | called by muse, mutect2
- PM20D1 | c.513C>T p.L171= | Silent (SNP) | VAF 34/372 reads (9%) | catalogued as COSV65648905; called by muse, mutect2
- PRSS22 | c.927G>A p.Q309= | Silent (SNP) | VAF 43/354 reads (12%) | catalogued as rs746359517; called by muse, mutect2, varscan2
- PRSS23 | c.40C>T p.L14= | Silent (SNP) | VAF 25/394 reads (6%) | catalogued as COSV54707496; called by muse, mutect2
- PTPRT | c.711G>A p.L237= | Silent (SNP) | VAF 42/291 reads (14%) | called by muse, mutect2, varscan2
- RNF32 | c.501C>T p.L167= | Silent (SNP) | VAF 27/340 reads (8%) | called by muse, mutect2
- RTN4 | c.12G>A p.L4= | Silent (SNP) | VAF 25/229 reads (11%) | catalogued as COSV100464059; called by muse, mutect2, varscan2
- SAXO2 | c.1116T>G p.P372= | Silent (SNP) | VAF 31/266 reads (12%) | called by muse, mutect2, varscan2
- SLC25A20 | c.291G>A p.K97= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as COSV59804496, COSV59804591; called by muse, mutect2
- SLC37A2 | c.75C>T p.I25= | Silent (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- SLC4A9 | c.2856G>A p.G952= (on ENST00000507527 / NM_001258428.2; = p.G928= on NM_031467.3) | Silent (SNP) | VAF 36/396 reads (9%) | called by muse, mutect2
- SRI | c.406T>C p.L136= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as rs745542159; called by muse, mutect2
- ST3GAL1 | c.807C>T p.T269= | Silent (SNP) | VAF 38/350 reads (11%) | catalogued as rs1441278139, COSV60613294; called by muse, mutect2, varscan2
- SYTL1 | c.141C>T p.G47= | Silent (SNP) | VAF 33/342 reads (10%) | catalogued as rs1490008367; called by muse, mutect2, varscan2
- TAF11L13 | c.102G>A p.G34= | Silent (SNP) | VAF 38/358 reads (11%) | called by muse, mutect2, varscan2
- TEX13C | c.2553G>A p.G851= | Silent (SNP) | VAF 49/602 reads (8%) | catalogued as rs1171211924; called by muse, mutect2
- TF | c.1827G>A p.R609= | Silent (SNP) | VAF 40/430 reads (9%) | catalogued as rs928316482; called by muse, mutect2
- TMEM35A | c.324C>T p.V108= | Silent (SNP) | VAF 54/512 reads (11%) | catalogued as rs767253603; called by muse, mutect2, varscan2
- TRIM58 | c.585G>A p.Q195= | Silent (SNP) | VAF 45/362 reads (12%) | catalogued as rs267598487; called by muse, mutect2, varscan2
- TSPEAR | c.1458C>T p.P486= | Silent (SNP) | VAF 19/391 reads (5%) | called by muse, mutect2
- TTK | c.1998G>A p.G666= | Silent (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- UBXN2B | c.807G>A p.L269= | Silent (SNP) | VAF 50/295 reads (17%) | called by muse, mutect2, varscan2
- WDR12 | c.303T>C p.D101= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- ZC3H12B | c.2079C>T p.G693= | Silent (SNP) | VAF 56/538 reads (10%) | called by muse, mutect2, varscan2
- ZNF354C | c.981C>T p.L327= | Silent (SNP) | VAF 49/522 reads (9%) | called by muse, mutect2
- ZNF423 | c.2103G>A p.V701= (on ENST00000563137 / NM_001379286.1; = p.V693= on NM_015069.4) | Silent (SNP) | VAF 42/446 reads (9%) | called by muse, mutect2
- CALN1 | c.*2921A>T | 3'UTR (SNP) | VAF 26/400 reads (7%) | called by muse, mutect2
- DCLK3 | c.-185G>A | 5'UTR (SNP) | VAF 20/240 reads (8%) | catalogued as rs939216851; called by muse, mutect2
- TTN | c.10360+1334G>A | Intron (SNP) | VAF 28/382 reads (7%) | called by muse, mutect2
